Somatic mutation profile of tumor specimen TCGA-HT-7603-01A (aliquot TCGA-HT-7603-01A-21D-2086-08) from TCGA case TCGA-HT-7603, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 29.8 years (10,883 days).
Specimen TCGA-HT-7603-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cd9c0e2-1201-4ffd-8fc0-495cf60224b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7603-10A (Blood Derived Normal), aliquot TCGA-HT-7603-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19b6a9fa-c672-4121-ab10-63c3899d8f9a

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 28/54 reads (52%) | hotspot (GDC flag); catalogued as rs919106518, COSV64870782; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 32/53 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEP95 | c.782T>G p.I261S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV73608594; called by muse, mutect2
- CHRNA6 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV52378519; called by muse, mutect2, varscan2
- CLSTN3 | c.2144A>G p.D715G | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV56933627, COSV56934014; called by muse, mutect2, varscan2
- CLUH | c.406C>T p.R136* (on ENST00000435359; = p.R174* on NM_015229.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV70927728; called by muse, mutect2, varscan2
- DAGLA | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs755291866, COSV57193971; called by muse, mutect2
- FNBP1 | c.39C>G p.N13K | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV63085398; called by muse, mutect2, varscan2
- GADD45GIP1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs763367169, COSV57533367; called by muse, mutect2, varscan2
- OR5P3 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.103); catalogued as COSV60428910, COSV60429575; called by muse, varscan2
- OR5P3 | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV60428923, COSV60428948; called by muse, varscan2
- RCBTB2 | c.1430A>G p.K477R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as COSV60649075; called by muse, mutect2, varscan2
- RIMBP2 | c.2482C>T p.R828* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as rs967487315, COSV55464433, COSV55485865; called by muse, mutect2, varscan2
- SALL1 | c.3949G>T p.D1317Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV51753266, COSV51763975; called by muse, mutect2, varscan2
- TMEM79 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs755500391, COSV55293202; called by muse, mutect2, varscan2
- TNRC6A | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.121); catalogued as COSV59361193; called by muse, mutect2, varscan2
- TNRC6A | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV59361202; called by muse, mutect2, varscan2
- UTP4 | c.1777C>G p.P593A | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV58732070; called by muse, mutect2, varscan2
- UTY | c.3455T>C p.V1152A | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV58868173; called by muse, mutect2, varscan2
- RBP3 | c.155T>C p.I52T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDIAS | c.1965A>G p.G655= | Silent (SNP) | VAF 10/179 reads (6%) | catalogued as COSV61271412; called by muse, mutect2
- DSG2 | c.3264T>C p.F1088= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV55196743; called by muse, mutect2, varscan2
- FAM124A | c.492C>T p.P164= (on ENST00000322475 / NM_001242312.2; = p.P200= on NM_145019.4) | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs781296689, COSV54474354; called by muse, mutect2, varscan2
- MTARC2 | c.667T>C p.L223= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs778724274, COSV63764996; called by muse, mutect2, varscan2
- TAOK3 | c.27A>G p.P9= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV66824768; called by muse, mutect2
- UBA2 | c.495G>A p.P165= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs772883163, COSV55827158, COSV55827295; called by muse, mutect2, varscan2
